CCDI case PBCKMA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/91591625-23f0-4afa-80fd-c607a65ba918

Demographics
Sex at birth: male.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 3.4 years (1,245 days).

Biospecimens (2 samples)
- Sample 0DU3LK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU3MQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
